Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A01Y, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A01Y-01A (Primary Tumor).

Sample IC

Findings and diagnosis of the problem:

This is an invasive rectum carcinoma (adenocarcinoma),
moderately differentiated - G 2,
with penetration of all layers of the wall - p T 3,
and penetration into lymphatic vessels - L 1
as well as with free resection margins and a free ligature
(corresponding to R 0),
with free lymph nodes (p N 0, 0/17)

as well as an associated portion of a biopsy conforming to the type of a lymph node with
reactive changes.

Tumor classification:

ICDO-DA-M

8140/3

G 2

p T 3,

L 1,

p N 0. R 0

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: rectum C20.9 p 3/3/11

Source: NCI Genomic Data Commons file 80268c63-2dae-4274-ac79-031db52d2d32 (TCGA-AG-A01Y.EFB05A46-D106-4E6D-A1DF-7CF90BE26FFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).